TCGA case TCGA-F5-6813 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/99d2c035-06a2-4bc3-8ff9-db875d232c93

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 70 years; Vital status: Dead; Days to death: 598 days (1.6 years).

Diagnoses (2; GDC holds 3 diagnosis records for this case, 1 of them empty or duplicates of those shown)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C49.4; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 70.2 years (25,651 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T4a; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 598 days (1.6 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 12; Lymph nodes tested: 12; Lymphatic invasion present: No; Non nodal tumor deposits: No; Perineural invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 70.4 years (25,716 days); Days to diagnosis: 65 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Liver; Surgery, NOS.

Follow-up (4 entries)
- Day 65 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 252 days; Disease response: With Tumor.
- Days to follow up: 598 days (1.6 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 21.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 85 kg; Height: 174 cm; BMI: 28.1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-F5-6813-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.5; Intermediate dimension: 1.3; Shortest dimension: 0.4.
  Slide TCGA-F5-6813-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 15; Percent necrosis: 5; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
  Slide TCGA-F5-6813-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 15; Percent necrosis: 5; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 5.
- Sample TCGA-F5-6813-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-F5-6813-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Rectum; Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Anatomic organ subdivision: Rectum; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 1, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form 2, New tumor event: New tumor event surgery: No; New tumor event site surgery: Liver; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 598 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 598 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 65 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-F5-6813-01A-11D-1825-01): tumor purity 0.67, ploidy 2.04, whole-genome doublings 0.
